Somatic mutation profile of tumor specimen TARGET-30-PAMVLG-01A (aliquot TARGET-30-PAMVLG-01A-01D) from TARGET case TARGET-30-PAMVLG, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 5.4 years (1,978 days).
Specimen TARGET-30-PAMVLG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ddaf6a87-27ec-4ddf-8552-2497359783e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAMVLG-10A (Blood Derived Normal), aliquot TARGET-30-PAMVLG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e9fda8b-1575-4e59-9898-7144c3b97dbb

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Silent 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH9 | c.515C>A p.S172Y | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV50309513; called by muse, mutect2, varscan2
- DLC1 | c.2933C>G p.S978C (on ENST00000276297 / NM_001348081.2; = p.S541C on NM_006094.5) | Missense Mutation (SNP) | VAF 61/112 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV52310568; called by muse, mutect2, varscan2
- DNAJC3 | c.1341A>T p.E447D | Missense Mutation (SNP) | VAF 89/163 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65131913; called by muse, mutect2, varscan2
- LPCAT2 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV50896497; called by muse, mutect2, varscan2
- LRRC30 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 32/512 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.789); catalogued as rs1441205740, COSV67301507; called by muse, mutect2
- MATK | c.930C>A p.G310= (on ENST00000310132 / NM_139355.3; = p.G311= on NM_002378.4) | Splice Region (SNP) | VAF 26/62 reads (42%) | catalogued as COSV59555282; called by muse, mutect2, varscan2
- PAXIP1 | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 38/61 reads (62%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.061); catalogued as COSV68186519; called by muse, mutect2, varscan2
- PELO | c.534T>A p.H178Q | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV50885402; called by muse, mutect2, varscan2
- SASH1 | c.1043G>T p.R348L | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.846); catalogued as COSV66562785, COSV66565857; called by muse, mutect2, varscan2
- SLC12A8 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.012); called by muse, mutect2
- EXOSC5 | c.510A>G p.T170= | Silent (SNP) | VAF 16/196 reads (8%) | catalogued as rs753440340; called by muse, mutect2
- SPAG16 | c.1788T>A p.I596= | Silent (SNP) | VAF 43/118 reads (36%) | catalogued as COSV56972815; called by muse, mutect2, varscan2
